Gene-level copy-number profile of tumor specimen TARGET-10-PANRDC-03A from TARGET case TARGET-10-PANRDC, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.5 years (539 days).
Specimen TARGET-10-PANRDC-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-ALL-P2.7db80fb9-45cd-5128-b6b5-c5403b7eaaf3.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-10-PANRDC-14A (bone marrow normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 402 have no estimate.
https://portal.gdc.cancer.gov/files/045cec51-c7b5-452a-8f99-c9bdd3e0dba9

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 79; copy number 1: 2,506; copy number 2: 57,439; copy number 3: 197.

Homozygous deletions (total copy number 0; autosomes only): 79 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:22,438,547–22,513,998, 42 genes: TRDD1, TRDD2, TRDD3, TRDJ1, TRDJ4, TRDJ2, TRDJ3, TRDC, TRDV3, TRAJ61, TRAJ60, TRAJ59, TRAJ58, TRAJ57, TRAJ56, TRAJ55, TRAJ54, TRAJ53, TRAJ52, TRAJ51, TRAJ50, TRAJ49, TRAJ48, TRAJ47, TRAJ46, TRAJ45, TRAJ44, TRAJ43, TRAJ42, TRAJ41, TRAJ40, TRAJ39, TRAJ38, TRAJ37, TRAJ36, TRAJ35, TRAJ34, TRAJ33, TRAJ32, TRAJ31, TRAJ30, TRAJ29.
- chr14:106,001,534–106,293,808, 37 genes: IGHVIII-2-1, IGHV1-3, IGHV4-4, IGHV7-4-1, IGHV2-5, IGHVIII-5-1, IGHVIII-5-2, IGHV3-6, IGHV3-7, IGHV3-64D, IGHV5-10-1, IGHV3-11, IGHVIII-11-1, IGHV1-12, IGHV3-13, IGHVIII-13-1, IGHV1-14, IGHV3-15, IGHVII-15-1, IGHV3-16, IGHVIII-16-1, IGHV1-17, SLC20A1P2, IGHV1-18, IGHV3-19, AC247036.1, IGHV3-20, IGHV3-21, IGHV3-22, IGHVII-22-1, IGHVIII-22-2, IGHV3-23, IGHV1-24, HOMER2P2, LINC00226, IGHV3-25, IGHVIII-25-1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 119. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
